Somatic mutation profile of tumor specimen C3N-01165-02 (aliquot CPT0093930010) from CPTAC case C3N-01165, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.1 years (23,060 days).
Specimen C3N-01165-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92852ce5-a5f0-49d5-8a0f-e769acf17a1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01165-31 (Blood Derived Normal), aliquot CPT0093970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01f28843-2632-416d-9c00-2ce10c891fdb

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 40/324 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 73/575 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 27/306 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs749902150, COSV64419079; called by muse, mutect2
- FAT2 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.245); catalogued as rs201835676; called by muse, mutect2, varscan2
- NLRC4 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs374259187; called by muse, mutect2
- PTPRS | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV53609338; called by muse, mutect2, varscan2
- SCG2 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.751); catalogued as COSV59539803; called by muse, mutect2, varscan2
- ZNF223 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs777005275, COSV69691221; called by muse, mutect2
- GPR25 | c.753C>A p.S251R | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); called by muse, mutect2
- KCNJ16 | c.738C>G p.I246M | Missense Mutation (SNP) | VAF 35/398 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2
- LRPAP1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 27/309 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.095); called by muse, mutect2
- MCM7 | c.1150G>C p.G384R | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIPOR2 | c.201dup p.E68Rfs*5 | Frame Shift Ins (INS) | VAF 24/283 reads (8%) | called by mutect2, pindel
- SPEF1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- TCEAL9 | c.199A>G p.N67D | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TOGARAM2 | c.2084T>C p.L695P | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- CFAP44 | c.186C>T p.D62= | Silent (SNP) | VAF 17/368 reads (5%) | called by muse, mutect2
- FAM110B | c.519C>T p.S173= | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- FAM120A | c.1170G>A p.Q390= | Silent (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- NEK10 | c.333C>A p.T111= | Silent (SNP) | VAF 27/194 reads (14%) | catalogued as COSV100412230, COSV58288920; called by muse, mutect2, varscan2
- STXBP5 | c.2127C>T p.R709= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as rs747661250; called by muse, mutect2, varscan2
- TRMT2B | c.804A>G p.R268= | Silent (SNP) | VAF 20/178 reads (11%) | called by muse, mutect2, varscan2
- FTH1 | c.115-50A>T | Intron (SNP) | VAF 30/458 reads (7%) | called by muse, mutect2
- NRXN1 | c.833-32771G>T | Intron (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
